Gene-level copy-number profile of tumor specimen TCGA-NH-A6GC-01A from TCGA case TCGA-NH-A6GC, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IVB; Age at diagnosis: 66.7 years (24,355 days).
Specimen TCGA-NH-A6GC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6faf8dd8-c78f-4db5-b621-0a7f17bb1399.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NH-A6GC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-NH-A6GC-01A|TCGA-NH-A6GC-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94c1583f-6023-4fe8-a240-f16e7cdc4998

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 891; copy number 2: 11,438; copy number 3: 23,292; copy number 4: 17,391; copy number 5: 5,930; copy number 6: 841; copy number 7: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NH-A6GC-01A-12D-A40O-01): tumor purity 0.78, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 32 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:7,914,514–13,034,326, 32 genes, copy number 7 (within-gene range 6–7): AL135923.2, AL135923.1, PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1.

Autosomal genes at a single copy (total copy number 1): 891. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
